Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9JQ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9JQ-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD-O-3
Carcinoma, papillary
renal cell 8260/3
Site: B Kidney NOS C64.9
4/28/14

Final Diagnosis

- A. RIGHT KIDNEY AND ADRENAL GLAND, NEPHRECTOMY AND ADENALECTOMY:
Renal cell carcinoma, papillary type. See Key Pathologic Findings.
Adrenal gland, no evidence of malignancy.
Surgical margins, free of malignancy.
Pathologic stage: pT1a NX MX.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Ancillary Testing

Immunoperoxidase stains (cytokeratin 7, cytokeratin 20, AMACR, vimentin) performed with appropriate positive and negative controls on blocks A4 and A7 support the diagnosis.

Key Pathological Findings

A: Kidney Resection

SPECIMEN LATERALITY:

Right

TUMOR SIZE (largest tumor if multiple):

Dimension: 3.1 cm

MACROSCOPIC EXTENT OF TUMOR:

Tumor limited to kidney

HISTOLOGIC TYPE:

Papillary renal cell carcinoma

SARCOMATOID FEATURES:

Not identified

TUMOR NECROSIS:

Present 5 %

HISTOLOGIC GRADE (Fuhrman Nuclear Grade):

II-III, predominantly II

MICROSCOPIC TUMOR EXTENSION:

Tumor limited to kidney

MARGINS:

Vascular, ureteral and surgical margins, uninvolved by carcinoma

ADRENAL GLAND:

Uninvolved by tumor

PERINEURAL INVASION:

Absent

ANGIOLYMPHATIC INVASION:

Absent

LYMPH-VASCULAR INVASION:

Absent

[page 2 of 2]
PRIMARY TUMOR (pT):

pT1a: Tumor 4 cm or less in greatest dimension, limited to the kidney

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

pMX

OTHER TUMORS AND/OR TUMOR-LIKE LESIONS:

Cyst(s): Benign cortical cysts

Specimen(s) Received

A RIGHT KIDNEY

Preoperative Diagnosis

Right renal mass

Gross Description

A. Specimen A is received fresh, labeled "right kidney" and consists of a kidney with moderate perinephric soft tissue, 462.3 g, 16.5 x 9.5 x 6.7 cm overall dimension. The adrenal gland is non-intact and ragged, 3 x 1.5 x 1 cm. The kidney (12.5 x 6.5 x 4.5 cm) is firm and inked black. The inferior pole exhibits an exophytic encapsulated nodule of the lateral aspect, 3.1 x 2.6 x 2.5 cm. Sectioned, the nodule is pale tan, solid and smooth, with scant necrosis (5%) and focal hemorrhage. The nodule grossly originates from the parenchyma, and does not penetrate the renal capsule or perinephric fat. The nodule does not involve the renal pelvis, calices or pelvic fat. The renal artery, vein and ureter are not affected by the nodule. Located in the superior and middle pole are several intraparenchymal cysts, containing clear serous fluid, 1 to 2.5 cm diameter. The cyst lining is smooth with no papillary excrescences noted. The papillae are blunted and the cortex is 8 mm thick. An external segment of ureter is noted (5.4 cm length x 3 mm diameter) and is probe patent. The renal vein is firm with moderate atherosclerotic changes and appears 40-50% occluded. A 5 mm orange-yellow ovoid calculus is identified in the renal pelvis. No constriction or dilation of the calices is identified.

Representative sections including all margins are submitted in A1-A10 as labeled:

- A1: Resection margin of renal artery, vein and ureter, tangential.
- A2: Representative of adrenal gland.
- A3-A4: Inferior pole lesion with perinephric fat and parenchyma, bisected.
- A5: Inferior pole lesion with parenchyma and perinephric fat.
- A6: Inferior pole lesion with parenchyma.
- A7: Inferior pole lesion with pelvic fat.
- A8: Mid pole cyst, cross section with perinephric fat.
- A9: Two cysts.
- A10: Normal kidney parenchyma.

The specimen is submitted for Tissue Procurement Laboratory as reflected in cassette A4.

Source: NCI Genomic Data Commons file 861ce744-c364-4665-bae9-f3a06e3b732d (TCGA-2Z-A9JQ.A2194453-658D-441C-AEE5-3C05DAADC243.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).